Surgical pathology report (de-identified scan), TCGA case TCGA-CG-4477, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Indivumed, specimen TCGA-CG-4477-01A (Primary Tumor).

Diagnosis:

This is a poorly differentiated adenocarcinoma of the cardiac and fundus region (gastric carcinoma of the intestinal type) of histopathological differentiation grade G3, with necroses, erosions/ulcerations of the inner tumor surface, with necroses, with solid tumor areas, with peritumorous chronic recurrent concomitant inflammation with acute inflammatory activity, with carcinomatous lymphangitis, with tumor infiltration of the parietal layers of the stomach extending into the outer layers of the tunica muscularis, with tumor-free lymph nodes (0/17) with a chronic lymphadenitis and tumor-free overview slices from all the parts of the resection material described.

According to the section preparations available, the tumor spread of the gastric carcinoma corresponds to a tumor stage of pT2a pN0 (0/174) MX; L1, R0.

Tumor classification:

ICDO-DA M 8140/3

Source: NCI Genomic Data Commons file 536be1f7-67b0-47e1-8666-f7e89e930f49 (TCGA-CG-4477.634642C1-7509-44EA-834E-3E18EED88DD7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).